Somatic mutation profile of tumor specimen TCGA-CH-5792-01A (aliquot TCGA-CH-5792-01A-11D-1576-08) from TCGA case TCGA-CH-5792, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.5 years (21,002 days).
Specimen TCGA-CH-5792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d994f8d1-ffe5-4352-bd14-1eba2e168ce3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5792-10A (Blood Derived Normal), aliquot TCGA-CH-5792-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4433137a-bdea-4d2d-9ef8-c2e23bfd60ed

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10 | c.3983C>A p.A1328D (on ENST00000398564; = p.A1303D on NM_014629.4) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV50642288; called by muse, mutect2
- ATP2B4 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as rs1483803600, COSV58174135; called by muse, mutect2, varscan2
- C16orf46 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV55150012; called by muse, mutect2, varscan2
- DPP6 | c.2035C>T p.R679W (on ENST00000377770 / NM_001364500.2; = p.R617W on NM_001936.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs759693906, COSV59596079; called by muse, mutect2
- ESCO1 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV52517998; called by muse, mutect2, varscan2
- HCFC2 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV57557828; called by muse, mutect2, varscan2
- HDAC6 | c.1698T>G p.F566L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV61927342; called by muse, mutect2, varscan2
- HDAC6 | c.1699G>C p.D567H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV61927350, COSV61928968; called by muse, mutect2, varscan2
- IGF1R | c.3449A>G p.K1150R | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157702045, COSV51269489; called by muse, mutect2, varscan2
- IZUMO2 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV53229115; called by muse, mutect2
- KEAP1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1371897807, COSV50260574, COSV50313513; called by muse, mutect2, varscan2
- KLF11 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs752934992, COSV59939918; called by muse, mutect2, varscan2
- LHCGR | c.1281T>A p.Y427* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | catalogued as COSV54292112, COSV54302767; called by muse, mutect2, varscan2
- NDST2 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as COSV55212583; called by muse, mutect2, varscan2
- NFIL3 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 34/232 reads (15%) | catalogued as COSV52682881; called by muse, mutect2, varscan2
- NOD1 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs771122098, COSV56110617; called by muse, mutect2, varscan2
- PDZRN3 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV55190338; called by muse, mutect2, varscan2
- RAB5C | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs767452695, COSV60524045; called by muse, mutect2, varscan2
- TNFRSF11B | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV52069249; called by muse, mutect2, varscan2
- TXLNG | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs781455729, COSV58112473; called by muse, mutect2, varscan2
- ZSWIM2 | c.1447T>A p.L483I | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1238485710, COSV54573597, COSV54579154; called by muse, mutect2, varscan2
- IGHV1-58 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IRS1 | c.1862del p.P621Qfs*15 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | called by mutect2, pindel, varscan2
- P2RX5 | c.184del p.L62Cfs*46 | Frame Shift Del (DEL) | VAF 30/223 reads (13%) | called by mutect2, pindel, varscan2
- TAF15 | c.217C>T p.Q73* (on ENST00000605844 / NM_139215.3; = p.Q70* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- CMYA5 | c.4482A>G p.K1494= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as COSV71404033; called by muse, mutect2
- CSMD1 | c.540C>T p.H180= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs368684088; called by muse, mutect2, varscan2
- MAPRE1 | c.297A>G p.G99= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV65032440; called by muse, mutect2, varscan2
- MST1R | c.3423G>A p.P1141= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs138521247; called by muse, mutect2
- OR10Z1 | c.645C>T p.T215= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as COSV63523744; called by muse, mutect2
- RNASEL | c.1776C>T p.R592= | Silent (SNP) | VAF 48/244 reads (20%) | catalogued as COSV62376156; called by muse, mutect2, varscan2
- VGF | c.288C>T p.P96= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1338535378, COSV50800815; called by muse, mutect2
- CD300LB | c.-72del | 5'UTR (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- PGM1 | c.247-5831A>G | Intron (SNP) | VAF 30/148 reads (20%) | catalogued as rs769782222, COSV64300006; called by muse, mutect2, varscan2
